CPTAC case C3L-02619 — Bronchus and lung — Squamous Cell Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f05dc58e-c9dc-48fc-bf07-e0aca961797a

Demographics
Sex at birth: male; Race: white; Year of birth: 1947; Vital status: Alive; Country of birth: Bulgaria.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Lower lobe, lung; Age at diagnosis: 70.2 years (25,633 days); Year of diagnosis: 2018; AJCC staging edition: 7th; AJCC clinical M: MX; AJCC pathologic T: T4; AJCC pathologic N: N1; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Residual disease: RX; Last known disease status: Tumor free; Days to last known disease status: 505 days (1.4 years); Progression or recurrence: no; Days to last follow up: 505 days (1.4 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 8.5 cm; Lymph node involvement: Positive; Lymph nodes positive: 1; Lymph nodes tested: 13; Margin status: Uninvolved.

Follow-up (2 entries)
- Days to follow up: 505 days (1.4 years); Disease response: Complete Response; ECOG performance status: 0.
- Days to follow up: 505 days (1.4 years); Disease response: Tumor Free; ECOG performance status: 0.

Other clinical attributes
- Weight: 120 kg; Height: 182 cm; BMI: 36.23; FEV1/FVC before bronchodilator (%): 90; FEV1 before bronchodilator (% of reference): 84.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 72; Cigarettes per day: 40; Tobacco smoking onset year: 1981; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker; Exposure duration years: 41.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-02619-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -9 days; Initial weight: 202 mg; Time between clamping and freezing: 25 minutes; Time between excision and freezing: 8 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-02619-21: Section location: Right Lower Lobe; Percent tumor nuclei: 60; Percent necrosis: 15.
- Sample C3L-02619-08: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -9 days; Initial weight: 276 mg; Time between clamping and freezing: 40 minutes; Time between excision and freezing: 23 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-02619-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -9 days; Method of sample procurement: Blood Draw.
